Somatic mutation profile of tumor specimen TCGA-24-2254-01A (aliquot TCGA-24-2254-01A-01W-0722-08) from TCGA case TCGA-24-2254, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.8 years (24,407 days).
Specimen TCGA-24-2254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c572b0d7-3c2f-45c8-bceb-31ffd9aa7d63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2254-10A (Blood Derived Normal), aliquot TCGA-24-2254-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fecd5b4-f092-4cfd-91d8-08cb360e56b8

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 34, Silent 13, Splice Site 4, Frame Shift Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 162/206 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.751A>T p.T251S | Missense Mutation (SNP) | VAF 127/342 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52923884; called by muse, mutect2, varscan2
- CDH8 | c.948C>G p.I316M | Missense Mutation (SNP) | VAF 269/347 reads (78%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); catalogued as COSV54886667, COSV54891243; called by muse, mutect2, varscan2
- CLDN10 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV100176040; called by muse, mutect2
- CLIP1 | c.1307+1G>A p.X436_splice | Splice Site (SNP) | VAF 48/61 reads (79%) | catalogued as COSV56805554, COSV56806046; called by muse, mutect2, varscan2
- CLIP3 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1412383944, COSV53325411; called by muse, mutect2, varscan2
- ELP1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV100534590; called by muse, mutect2
- FERMT1 | c.533-1G>A p.X178_splice | Splice Site (SNP) | VAF 24/259 reads (9%) | catalogued as rs868202613, COSV99451005; called by muse, mutect2
- FKBP7 | c.47A>T p.Y16F | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV51847058; called by muse, mutect2, varscan2
- GAL3ST4 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV57587612; called by muse, mutect2, varscan2
- GCM2 | c.595C>G p.Q199E | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV65276214; called by muse, mutect2, varscan2
- GNA14 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV59027155; called by muse, mutect2, varscan2
- HAO2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 122/325 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as rs770017018, COSV58041356; called by muse, mutect2, varscan2
- INSIG2 | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55523217; called by muse, varscan2
- KCNK9 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 60/69 reads (87%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs765326608, COSV57279006; called by muse, mutect2, varscan2
- KIAA1191 | c.808T>G p.L270V | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV53799640; called by muse, mutect2, varscan2
- LIFR | c.404T>A p.I135N | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV54696118; called by muse, mutect2, varscan2
- MAP3K15 | c.3583G>C p.V1195L | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV58835148; called by muse, mutect2, varscan2
- MAP3K19 | c.100A>T p.N34Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV59640973; called by muse, mutect2, varscan2
- MDH1B | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100982123; called by muse, mutect2, varscan2
- MDH1B | c.867A>T p.E289D | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as COSV100982124; called by muse, mutect2, varscan2
- MTOR | c.3313G>A p.A1105T | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs529153687, COSV100815690, COSV63869322; called by muse, mutect2, varscan2
- MYBPC3 | c.3692G>A p.S1231N | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV57030459; called by muse, mutect2, varscan2
- PGLYRP4 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs200715095, COSV62835998; called by muse, mutect2, varscan2
- PLAAT5 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs144730159; called by muse, mutect2, varscan2
- PLEKHG4B | c.1150G>T p.E384* (on ENST00000283426; = p.E740* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as rs138938524, COSV52043292, COSV52051979; called by muse, mutect2, varscan2
- RELN | c.1441+1G>A p.X481_splice | Splice Site (SNP) | VAF 50/194 reads (26%) | catalogued as COSV59023487; called by muse, varscan2
- SCEL | c.1023T>A p.N341K (on ENST00000349847 / NM_144777.3; = p.N321K on NM_003843.4) | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.073); catalogued as COSV62994176; called by muse, mutect2, varscan2
- SLC36A3 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV100077314; called by muse, varscan2
- SLC36A3 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs147738288, COSV58857787; called by muse, varscan2
- SRL | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs763106612, COSV68424036; called by muse, mutect2, varscan2
- TBC1D31 | c.671+1G>C p.X224_splice | Splice Site (SNP) | VAF 7/115 reads (6%) | catalogued as COSV99782326; called by muse, mutect2
- TRPM3 | c.4504C>T p.R1502C (on ENST00000357533 / NM_001366142.2; = p.R1357C on NM_020952.6) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1179953388, COSV62583854; called by muse, mutect2, varscan2
- TTN | c.9065C>T p.T3022I (on ENST00000591111; = p.T2976I on NM_003319.4) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | PolyPhen possibly damaging (0.836); catalogued as COSV100593039; called by muse, mutect2
- UBR2 | c.4765G>T p.D1589Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV65751618; called by muse, mutect2
- UGDH | c.731C>G p.T244R | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100328303; called by muse, mutect2
- VWF | c.8332C>T p.R2778W | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs368634026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF189 | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 173/413 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52276354; called by muse, mutect2, varscan2
- ARHGAP18 | c.492del p.K164Nfs*54 | Frame Shift Del (DEL) | VAF 144/459 reads (31%) | called by mutect2, pindel, varscan2
- HAS1 | c.1217T>A p.V406E | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2
- PHTF2 | c.938del p.G313Efs*3 (on ENST00000248550 / NM_001366089.1; = p.G275Efs*3 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/113 reads (36%) | called by mutect2, pindel, varscan2
- SAP130 | c.1354_1366del p.E452* | Frame Shift Del (DEL) | VAF 54/134 reads (40%) | called by mutect2, varscan2
- ATP2A3 | c.783C>A p.S261= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV59232672; called by muse, mutect2, varscan2
- CHRM3 | c.1464A>G p.K488= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV55097271; called by muse, mutect2, varscan2
- DCST1 | c.798G>A p.K266= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV55061718; called by muse, mutect2, varscan2
- EMILIN3 | c.1845C>G p.A615= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV60037804; called by muse, mutect2, varscan2
- KANSL1L | c.2730C>G p.T910= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV55995098; called by mutect2, varscan2
- MASP1 | c.906A>G p.P302= | Silent (SNP) | VAF 108/167 reads (65%) | catalogued as COSV51462420; called by muse, mutect2, varscan2
- MC5R | c.807C>T p.Y269= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV61255284; called by muse, mutect2
- MYH1 | c.5730C>T p.A1910= | Silent (SNP) | VAF 562/685 reads (82%) | catalogued as rs753589780, COSV56853849; called by muse, mutect2, varscan2
- MYO3B | c.1698A>T p.G566= | Silent (SNP) | VAF 96/252 reads (38%) | catalogued as COSV58711568; called by muse, mutect2, varscan2
- PDSS2 | c.474T>G p.A158= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV64649403; called by muse, mutect2
- PHF2 | c.2610C>T p.F870= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV63682781; called by muse, mutect2, varscan2
- RHOBTB2 | c.801C>T p.D267= | Silent (SNP) | VAF 49/64 reads (77%) | catalogued as rs547602967, COSV52572481; called by muse, mutect2, varscan2
- TNFRSF1B | c.657A>T p.P219= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
